MMRF case MMRF_2080 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/566c7e1c-5180-4518-8559-27563c7ad629

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.2 years (17,599 days); ISS stage: III; Days to last known disease status: 962 days (2.6 years); Days to last follow up: 962 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 212 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 108 days; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 212 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 4.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.42 mg/dL; Immunoglobulin G 69.3 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 12.6 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 12.6 g/dL; Glucose 4.57 mmol/L; C-Reactive Protein 0.29 mg/dL.
- Day 70 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL; Immunoglobulin G 3.05 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 452 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.39 mmol/L.
- Day 165 (ECOG 1): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 6.38 mmol/L.
- Day 260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 5.12 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.58 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.6 mmol/L.
- Day 346 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 6 mmol/L.
- Day 428 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 7.38 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.48 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.72 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 8.08 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.79 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 5.45 mmol/L.
- Day 594 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 9.44 g/L; Immunoglobulin A 1.92 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.9 g/dL; Glucose 6.05 mmol/L.
- Day 709 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 5.5 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 5.06 mmol/L.
- Day 794: Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 9.38 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 5.17 mmol/L.
- Day 877 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.23 mmol/L.
- Day 962 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 8 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -10: Weight: 61 kg; Height: 159 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2080_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2080_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
